Gene-level copy-number profile of tumor specimen TCGA-DC-6683-01A from TCGA case TCGA-DC-6683, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 43.6 years (15,918 days).
Specimen TCGA-DC-6683-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.f7185ab1-a045-4b02-8f0e-9eef10a29610.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DC-6683-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fd89f424-5761-47a3-afb2-58d18e126537

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 746; copy number 2: 11,146; copy number 3: 30,175; copy number 4: 10,917; copy number 5: 5,488; copy number 6: 52; copy number 7: 321; copy number 9: 94; copy number 11: 879.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DC-6683-01A-11D-1825-01): tumor purity 0.61, ploidy 3.18, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,294 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:25,141,536–46,515,958, 386 genes, copy number 7–9 (broad region; genes not listed).
- chr13:109,101,261–110,713,603, 29 genes, copy number 7 (within-gene range 5–7): MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1, NAXD, CARS2.
- chr20:26,103,416–58,451,101, 724 genes, copy number 11 (broad region; genes not listed).
- chr20:60,055,853–64,313,132, 155 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 746. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
